Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A3MU, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A3MU-06A (Metastatic).

DIAGNOSIS

Patient ID -

100-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary C17.3
hu
1/7/12
hu

- (A) LEFT LOWER AXILLARY MASS, EXCISION:
MELANOMA INVOLVING FIBROADIPOSE TISSUE/POSSIBLY A COMPLETELY REPLACED
BY TUMOR LYMPH NODE.
THE TUMOR MEASURES 30 X 20 X 12 MM (AS PER GROSS REPORT).
As per gross report, the tissue edges appear free of tumor.

Source: NCI Genomic Data Commons file 5c9b4c82-5431-473f-9816-f81a615ec563 (TCGA-D3-A3MU.13735CBA-392B-4D76-B29A-30991850A609.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).